Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A1Y7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A1Y7-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1
3/6/11 *lw*

Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender:
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Specimen(s) Received

1. Lymph-Node: Right Common Iliac Node Q/S
2. Pelvic: Right pelvic nodes
3. Lymph node: Right para aortic nodes
4. Uterus: Uterus, cervix, bilateral tubes and ovaries

Diagnosis

1. Lymph nodes, right common iliac:
- Negative for carcinoma (0/2)

2. Lymph nodes, right pelvic:
- Negative for carcinoma (0/1)

3. Lymph nodes, paraaortic:
- Negative for carcinoma (0/8)

4. Uterus, cervix, & bilateral tubes and ovaries:

Uterus:

ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, FIGO GRADE 3/3:

- extension into greater than 50% of myometrial thickness
- tumor involves the lower uterine segment, it approaches but doesn't involve the endocervix
- maximum depth of invasion 11 mm.
- lymphovascular space invasion present
- endometrial polyp with complex atypical hyperplasia present
- adenomyosis; leiomyoma

Cervix:

- Negative for carcinoma

Fallopian tubes:

- Negative for carcinoma

Left ovary:

- Negative for carcinoma

Right ovary:

- Serous cystadenofibroma
- Negative for carcinoma

[page 2 of 3]
Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes Performed: Para-aortic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Site:	Other: anterior and posterior
Tumor Size:	Greatest dimension: 3.9 cm Additional dimension: 4 cm
Histologic Type:	Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade:	FIGO grade 3
Myometrial Invasion:	Present Depth of invasion: 11 mm Myometrial thickness: 17 mm
Involvement of Cervix:	Not involved
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved Vagina not applicable Right parametrium not applicable Left parametrium not applicable Omentum not applicable Rectal wall not applicable Bladder wall not applicable Pelvic wall not applicable Bladder mucosa and/or bowel mucosa not applicable
Margins:	Uninvolved by invasive carcinoma
Lymph-Vascular Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1b (IB): Tumor invades more than or one-half of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Pelvic lymph nodes examined: 3 Pelvic lymph nodes involved: 0 Para-aortic lymph nodes examined: 8 Para-aortic lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Complex atypical hyperplasia Other: endometrial polyp

by:

Electronically verified

, MD

[page 3 of 3]
Clinical History

Endo Ca

Gross Description

1- Specimen is labeled with the patient's name and as right common iliac node. Two lymph nodes identified, one measures 1.3 cm, and the other is 0.5 cm in maximum dimension.

2. Specimen is labeled with the patient's name and as right pelvic nodes. Specimen consists of two fragments of unoriented fatty tissue the largest fragment measuring 1.0 x 1.0 x 0.5 cm. The specimen is submitted in toto in one block.

2A. fatty tissue

3. The specimen is labeled with the patient's name and as right para-aortic nodes. The specimen consists of one piece of fibrofatty tissue measuring 3.0 x 2.0 x 0.75 cm. the specimen is submitted in toto in two blocks

3A-B multiple nodes and fibrofatty tissue.

4. Specimen is labeled with the patient's name and uterus cervix bilateral tubes and ovaries. The specimen consists of a uterus cervix bilateral ovaries. The left fallopian tube appears to be missing. The left and right fimbria are present. The specimen has a fresh weight of 200.2 g and measures 9.5 SI x 7.0ML x 5.0 cm AP. The serosal surface of the uterus is nodular, tan and smooth. The cervix measures 3.5 cm in diameter The OS is 0.8 cm and is slit-shaped. The right fallopian tube measures 4.0 cm in length and 0.7 cm in diameter. The right ovary measures 2.4 x 1.5 x 1.2 cm and is grossly unremarkable. The left ovary measures 2.0 x 1.0 x 0.8 cm and is grossly unremarkable. Left adnexal tissue measures 4.0 x 0.8 cm. The opened endometrial cavity reveals a friable polypoid and papillary tumor measuring 3.9 cm SI and 4.0 cm ML. The tumor is 2.5 cm in maximal thickness and appears to invade into 50% of the myometrium in the anterior fundal portion of the uterus. The posterior endometrium involved with the tumor has a maximal thickness of 1.0 cm. The posterior portion of the opened cavity shows a round mass consistent with a fibroid measuring 2.0 x 3.0 cm x 2.0cm. The posterior portion of the lower uterine segment also shows a small polyp measuring 1.0 x 0.5 x 0.25 cm. The endometrium is tan in color.

4A posterior cervix and lower uterine segment

4B-C posterior lower uterine segment and polyp serially sectioned

4D posterior uterine fibroid bisected

4E posterior uterus involved with tumor bisected

4F posterior uterus with tumor deepest invasion

4G-H anterior cervix and lower uterine segment bisected

4I-J anterior uterus involved with tumor deepest invasion

4 K-L anterior uteri involved with tumor

4M-N anterior uterus involved with tumor

4O-P left fimbria sectioned longitudinally

4Q left adnexal tissue

4R-S left ovary and paraovarian tissue

4 T paraovarian tissue

4U-V right fimbria longitudinally sectioned and right tube

4W-X right ovary

4Y and paraovarian tissue

Quick Section Diagnosis

1. Right Common Iliac Node: Lymph nodes, negative for malignancy.

Called at

MD

Source: NCI Genomic Data Commons file 74c5a448-e655-40ee-9d57-7558186df7e9 (TCGA-EO-A1Y7.88AABD4B-ECB4-4748-B59F-BD4AE0621BFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).